Surgical pathology report (de-identified scan), TCGA case TCGA-BF-AAP0, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-AAP0-06A (Metastatic).

Case #

Patient: **Age (years):** **Gender:** Female

Clinical diagnosis: Melanoma

Date of procurement:

Sample:

Gross description:

The material presented – Auxillary lymph node, surgical resection

Microscopic description:

Received axillary lymph node presented with metastatic melanoma

Final diagnosis: Metastatic melanoma

ICD O-3

Melanoma NOS 8720/3

Site: Axillary lymph node C77.3

JW 4/22/14

Confidential

Source: NCI Genomic Data Commons file 61e851cf-d62f-4e81-888a-8176400f949a (TCGA-BF-AAP0.EFF48970-C0F0-4FFE-8891-26A96BBF54FC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).